Somatic mutation profile of tumor specimen TCGA-B3-3925-01A (aliquot TCGA-B3-3925-01A-01D-1458-08) from TCGA case TCGA-B3-3925, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 52.6 years (19,224 days).
Specimen TCGA-B3-3925-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cda0fdf1-1e2c-4d34-804b-7cfcabe812d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B3-3925-10A (Blood Derived Normal), aliquot TCGA-B3-3925-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19777824-08fb-463d-9773-00d634f024b8

The open-access MAF lists 80 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 2, 3'Flank 2, In Frame Del 2, 5'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL592490.1 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69427449; called by muse, mutect2
- AMY2B | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 189/1066 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs143243690; called by muse, mutect2, varscan2
- ASB15 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV51923926; called by muse, mutect2, varscan2
- ATP6V1A | c.479C>G p.S160W | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs760446373; called by muse, mutect2, varscan2
- DDR1 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 133/452 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764833803; called by muse, mutect2, varscan2
- GIPR | c.1167C>G p.S389R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs529800464; called by muse, mutect2, varscan2
- GNAZ | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV50737110; called by muse, mutect2, varscan2
- IGHV3-30 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.308); catalogued as rs752676641; called by muse, mutect2, varscan2
- MYH7 | c.4459G>A p.A1487T | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs766909770, COSV62524750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLM | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs375526665; called by muse, varscan2
- RAF1 | c.1171A>T p.R391W | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368807126; called by muse, mutect2, varscan2
- ROS1 | c.6723A>C p.E2241D | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100876871; called by muse, mutect2
- SIGLEC9 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV99142885; called by muse, mutect2, varscan2
- TOP2B | c.4408G>T p.D1470Y (on ENST00000264331 / NM_001330700.2; = p.D1465Y on NM_001068.3) | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs1253027961, COSV51971629; called by muse, mutect2, varscan2
- ZFP41 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs761878631, COSV58087715; called by muse, mutect2, varscan2
- ZZEF1 | c.5903G>A p.G1968E | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as rs762767015; called by muse, mutect2
- ABCE1 | c.1144+1G>A p.X382_splice | Splice Site (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 50/187 reads (27%) | called by muse, mutect2, varscan2
- ANAPC5 | c.2093_2096del p.K698Tfs*53 | Frame Shift Del (DEL) | VAF 115/270 reads (43%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.5165del p.N1722Tfs*5 (on ENST00000310343 / NM_001378025.1; = p.N1373Tfs*5 on NM_014715.4) | Frame Shift Del (DEL) | VAF 62/204 reads (30%) | called by mutect2, pindel, varscan2
- BMP1 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CALML4 | c.115A>C p.S39R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC63 | c.861G>C p.K287N | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CCDC9B | c.74del p.F25Sfs*33 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- CD2AP | c.1902_1910del p.A635_L637del | In Frame Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel
- CD40 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP170 | c.4586G>T p.S1529I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DEPDC5 | c.823A>T p.K275* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- GIGYF2 | c.2370+2T>A p.X790_splice | Splice Site (SNP) | VAF 112/342 reads (33%) | called by muse, varscan2
- GLDN | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GYS2 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 168/334 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- JAG2 | c.3505G>A p.A1169T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.084); called by muse, mutect2
- KHDC4 | c.398G>C p.S133T | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- LCOR | c.1107_1109del p.L370del | In Frame Del (DEL) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- LRIG2 | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM | c.5262T>G p.D1754E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- OGG1 | c.820_821insAA p.I274Kfs*133 | Frame Shift Ins (INS) | VAF 30/78 reads (38%) | called by mutect2, varscan2
- OGG1 | c.821delinsAAA p.I274Kfs*133 | Frame Shift Ins (INS) | VAF 28/73 reads (38%) | called by mutect2*, pindel, varscan2*
- PLCB2 | c.580A>T p.K194* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- POSTN | c.1511A>C p.K504T | Missense Mutation (SNP) | VAF 129/387 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PYROXD2 | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- QRICH2 | c.3449A>T p.Q1150L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RAB27B | c.346_349del p.Q116Cfs*12 | Frame Shift Del (DEL) | VAF 37/191 reads (19%) | called by mutect2, pindel, varscan2
- RAET1L | c.630A>T p.G210= | Splice Region (SNP) | VAF 76/211 reads (36%) | called by muse, mutect2, varscan2
- RFX2 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLX4 | c.2466G>C p.M822I | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SNTB1 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 59/205 reads (29%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.2747G>A p.W916* | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- SRCAP | c.3043C>A p.P1015T | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- STON1 | c.1184A>G p.E395G | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBCD | c.3109G>C p.E1037Q | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- TIGD2 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- TMCC2 | c.1216G>T p.V406F | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TSFM | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USF1 | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- VPS13C | c.6141G>C p.K2047N (on ENST00000644861 / NM_020821.3; = p.K2004N on NM_017684.5) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- VWC2L | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 85/282 reads (30%) | called by muse, mutect2, varscan2
- ZAN | c.6962G>T p.S2321I | Missense Mutation (SNP) | VAF 137/278 reads (49%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZNFX1 | c.586A>G p.S196G | Missense Mutation (SNP) | VAF 132/277 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CABIN1 | c.795T>A p.I265= | Silent (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- CDKL2 | c.504A>G p.R168= | Silent (SNP) | VAF 44/124 reads (35%) | called by muse, varscan2
- COL17A1 | c.4095T>C p.A1365= | Silent (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- CTPS2 | c.1242T>G p.L414= | Silent (SNP) | VAF 55/80 reads (69%) | called by muse, mutect2, varscan2
- FBXO11 | c.1440A>C p.A480= (on ENST00000403359 / NM_001190274.2; = p.A396= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV57026506; called by muse, mutect2, varscan2
- HDHD2 | c.90A>G p.E30= | Silent (SNP) | VAF 73/205 reads (36%) | called by muse, mutect2, varscan2
- IMMT | c.2253A>C p.G751= | Silent (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- MUC17 | c.12657G>A p.T4219= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs200175178; called by muse, mutect2, varscan2
- MUC5AC | c.15075C>T p.G5025= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs748170322; called by muse, mutect2, varscan2
- MXRA5 | c.5007T>C p.S1669= | Silent (SNP) | VAF 210/278 reads (76%) | called by muse, mutect2, varscan2
- MYO5B | c.1305G>A p.G435= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs746993416; called by muse, mutect2, varscan2
- MYO9A | c.3373A>C p.R1125= | Silent (SNP) | VAF 46/119 reads (39%) | called by muse, mutect2, varscan2
- PAOX | c.588C>T p.G196= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- PCDH18 | c.2388C>T p.H796= | Silent (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- PSMC4 | c.1065T>C p.S355= | Silent (SNP) | VAF 94/275 reads (34%) | called by muse, mutect2, varscan2
- PTPRE | c.570C>A p.I190= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs991804759; called by muse, mutect2, varscan2
- SOX10 | c.555G>A p.Q185= | Silent (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1418G>A | RNA (SNP) | VAF 7/10 reads (70%) | catalogued as rs1330339765; called by muse, mutect2, varscan2
- POM121C | chr7:75416562 A>G | 3'Flank (SNP) | VAF 84/180 reads (47%) | called by muse, mutect2, varscan2
- PREP | c.-48G>C | 5'UTR (SNP) | VAF 55/164 reads (34%) | catalogued as rs774243006, COSV64872553; called by muse, mutect2, varscan2
- RUFY3 | chr4:70793847 A>G | 3'Flank (SNP) | VAF 31/92 reads (34%) | catalogued as COSV56917737; called by muse, mutect2, varscan2
